Somatic mutation profile of tumor specimen C3L-01558-01 (aliquot CPT0390330006) from CPTAC case C3L-01558, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 51.2 years (18,688 days).
Specimen C3L-01558-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5863e10c-9585-4336-b939-a2317135b9e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01558-31 (Blood Derived Normal), aliquot CPT0390390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7be39819-ef9d-4543-82bf-0668b1e76fa9

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Frame Shift Del 2, Intron 2, Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGTR2 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 122/182 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64156805; called by muse, mutect2, varscan2
- ATF7IP2 | c.7A>G p.S3G | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs778902470; called by mutect2, varscan2
- LAMA2 | c.6226G>A p.V2076I | Missense Mutation (SNP) | VAF 147/367 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs767444868; called by muse, mutect2, varscan2
- SPATA6L | c.185A>G p.E62G | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs1199923685; called by muse, mutect2, varscan2
- CCDC88A | c.1954A>G p.K652E | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CLEC4G | c.61_65delinsA p.W21Nfs*26 | Frame Shift Del (DEL) | VAF 47/207 reads (23%) | called by pindel, varscan2*
- DDX56 | c.1486C>G p.L496V | Missense Mutation (SNP) | VAF 116/359 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- FASTKD5 | c.1813A>G p.R605G | Missense Mutation (SNP) | VAF 101/313 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HOXC6 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 150/343 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- HOXD9 | c.78del p.I26Mfs*67 | Frame Shift Del (DEL) | VAF 84/304 reads (28%) | called by mutect2, pindel, varscan2
- KIF7 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KRTAP10-12 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 216/647 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- RGS22 | c.2246T>A p.M749K | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- VILL | c.2340_2360del p.R780_S786del | In Frame Del (DEL) | VAF 29/232 reads (13%) | called by mutect2, pindel, varscan2
- ZFX | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.508); called by muse, mutect2
- ANXA1 | c.651C>T p.D217= | Silent (SNP) | VAF 65/250 reads (26%) | catalogued as rs370232910, COSV99973784, COSV99974060; called by muse, mutect2, varscan2
- MUC5AC | c.13914C>T p.D4638= | Silent (SNP) | VAF 52/311 reads (17%) | catalogued as rs200981907; called by muse, mutect2, varscan2
- HNF1A | c.1108-41G>C | Intron (SNP) | VAF 85/266 reads (32%) | called by muse, mutect2, varscan2
- SHROOM3 | c.3753+34G>T | Intron (SNP) | VAF 99/278 reads (36%) | called by muse, mutect2, varscan2
